Somatic mutation profile of tumor specimen 0DUXPP from CCDI case PBCLLW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.9 years (320 days).
Specimen 0DUXPP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ac28d70-ad5e-4895-afd3-8c939c6ac4c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXO1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df33d889-114b-4c6b-b4a8-5114d728e86b

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 5'UTR 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2AK4 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- EGR4 | c.30G>A p.P10= | Silent (SNP) | VAF 23/409 reads (6%) | catalogued as rs943240201; called by muse, mutect2
- CPT1C | c.*83T>C | 3'UTR (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- RPS6KA5 | c.-25C>A | 5'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
